Somatic mutation profile of tumor specimen 0DBXXW from CCDI case PBBLSC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.9 years (4,356 days).
Specimen 0DBXXW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fb8fd40-3060-4fae-af44-e2ad28610a28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBXXV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/747e9630-841a-43ae-b75c-af6c722ad057

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, Splice Region 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 496/1162 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1580T>G p.V527G (on ENST00000288602 / NM_001374244.1; = p.V487G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 138/899 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs397516893, CM071573, COSV56274656; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 529/939 reads (56%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 298/731 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 405/844 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CLCA2 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 229/638 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs373032365; called by muse, varscan2
- OBSCN | c.7780G>A p.G2594R | Missense Mutation (SNP) | VAF 265/347 reads (76%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.781); catalogued as rs367882449, COSV52741294; called by muse, mutect2, varscan2
- PCDHGA8 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 294/743 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs1474865202; called by muse, mutect2, varscan2
- FMN1 | c.3356_3359dup p.L1121Afs*4 (on ENST00000616417 / NM_001277313.2; = p.L898Afs*4 on NM_001103184.4) | Frame Shift Ins (INS) | VAF 291/754 reads (39%) | called by mutect2, varscan2
- PCLO | c.9017dup p.Y3007Lfs*2 | Frame Shift Ins (INS) | VAF 196/486 reads (40%) | called by mutect2, varscan2
- PIBF1 | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 355/901 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- RPS6KB2 | c.78+4A>C | Splice Region (SNP) | VAF 78/213 reads (37%) | called by muse, mutect2, varscan2
- SETD1B | c.5893C>G p.L1965V | Missense Mutation (SNP) | VAF 169/436 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TIAM2 | c.3717_3719del p.T1240del | In Frame Del (DEL) | VAF 398/854 reads (47%) | called by mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 27/982 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- YTHDC2 | c.2885A>G p.N962S | Missense Mutation (SNP) | VAF 218/569 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- DNAH11 | c.2499C>T p.N833= | Silent (SNP) | VAF 163/443 reads (37%) | catalogued as rs201231307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPA2 | c.975C>T p.R325= | Silent (SNP) | VAF 105/202 reads (52%) | catalogued as rs759623189, COSV55969753; called by muse, mutect2, varscan2
- SLC22A15 | c.375A>G p.G125= | Silent (SNP) | VAF 219/1156 reads (19%) | called by muse, mutect2, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 26/978 reads (3%) | catalogued as rs1267156464; called by muse, mutect2
- CCDC142 | c.*95T>C | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, varscan2
- RIC8B | c.84+506G>A | Intron (SNP) | VAF 128/289 reads (44%) | called by muse, mutect2, varscan2
- SHISA8 | chr22:41910476 C>T | 3'Flank (SNP) | VAF 74/170 reads (44%) | catalogued as rs1296164904; called by muse, mutect2, varscan2
